CCDI case PBBVCM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ef081c1b-5f7a-4598-a2b7-e175b22740ce

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,789 days).

Biospecimens (3 samples)
- Sample 0DNYNI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNYNO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNYO2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
